Gene-level copy-number profile of tumor specimen TCGA-AR-A0U3-01A from TCGA case TCGA-AR-A0U3, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.6 years (21,755 days).
Specimen TCGA-AR-A0U3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.c64f2c9b-e2e4-4a48-94e8-7f76569c8b7b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A0U3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f66f6bb-5bea-4636-a4f4-750bc1837e4c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 104; copy number 1: 21,366; copy number 2: 33,812; copy number 3: 1,916; copy number 4: 1,934; copy number 5: 248; copy number 6: 164; copy number 7: 94; copy number 8: 63; copy number 10: 36; copy number 13: 7; copy number 16: 7; copy number 19: 56.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A0U3-01A-11D-A107-01): tumor purity 0.79, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 104 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:1,823,926–2,926,689, 19 genes (within-gene range 0–1): ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1.
- chr22:15,290,718–17,165,445, 84 genes (broad region; genes not listed).
- chr22:17,192,936–17,193,308, 1 gene: AC005300.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 666 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:81,666,477–84,819,589, 26 genes, copy number 5–16: AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1, SUCLG1, DNAH6, DUXAP1, LDHAP7.
- chr8:36,987,977–38,973,912, 63 genes, copy number 13–19 (broad region; genes not listed).
- chr8:40,298,697–43,131,180, 63 genes, copy number 7–8 (within-gene range 1–8) (broad region; genes not listed).
- chr8:93,698,561–94,104,322, 17 genes, copy number 6: CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1.
- chr8:100,895,771–100,958,180, 5 genes, copy number 5: RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P.
- chr8:103,153,394–103,298,772, 1 gene, copy number 8 (within-gene range 2–8): BAALC-AS1.
- chr8:103,228,425–104,589,024, 23 genes, copy number 5–8: AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1, DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2.
- chr8:104,699,479–104,703,555, 1 gene, copy number 5: AC012564.1.
- chr8:110,766,863–114,791,929, 24 genes, copy number 5–7: AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2.
- chr8:128,634,199–129,683,770, 6 genes, copy number 5 (within-gene range 4–5): CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr11:67,119,263–68,616,711, 77 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr11:69,012,283–70,207,390, 34 genes, copy number 7: MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1.
- chr11:70,278,921–70,279,297, 1 gene, copy number 7: H2AZP4.
- chr11:70,283,955–70,284,070, 1 gene, copy number 7: MIR548K.
- chr19:6,887,566–7,561,764, 27 genes, copy number 5 (within-gene range 1–5): ADGRE1, AC020895.2, AC020895.1, Metazoa_SRP, ADGRE4P, AC025278.1, AC025278.2, AC025278.3, MBD3L2B, MBD3L5, MBD3L4, MBD3L2, MBD3L3, ZNF557, INSR, AC119396.1, AC008878.3, AC119396.2, ARHGEF18, PEX11G, TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1, AC008878.2, PNPLA6.
- chr19:33,621,953–36,246,257, 150 genes, copy number 5 (broad region; genes not listed).
- chr19:39,538,707–40,299,584, 40 genes, copy number 8: EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P.
- chr19:40,778,216–41,096,195, 20 genes, copy number 5 (within-gene range 1–5): RAB4B, RAB4B-EGLN2, AC008537.4, EGLN2, AC008537.1, CYP2T1P, CYP2F2P, AC008537.2, AC008537.3, CYP2A6, CYP2A7, CYP2G1P, CYP2A7P2, CYP2B7P, AC092071.1, CYP2B6, CYP2A7P1, CYP2G2P, AC008962.1, CYP2A13.
- chr19:50,968,193–51,826,190, 79 genes, copy number 6–10 (within-gene range 1–10) (broad region; genes not listed).
- chr19:51,888,025–52,030,240, 8 genes, copy number 6: ZNF649-AS1, ZNF649, AC011460.1, ZNF613, ZNF350-AS1, ZNF350, ZNF615, ZNF614.

Autosomal genes at a single copy (total copy number 1): 21,179. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
